Gene-level copy-number profile of specimen HCM-CSHL-0807-C54-85B from HCMI case HCM-CSHL-0807-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3.
Specimen HCM-CSHL-0807-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fc3a876-13ef-446b-8a59-f737abea900c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0807-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/9ed22673-5c2e-4b36-8f58-b38c571e1447

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 46; copy number 2: 55,869; copy number 3: 27; copy number 4: 2,462.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
